Somatic mutation profile of tumor specimen 0DLJX3 from CCDI case PBBZFR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,428 days).
Specimen 0DLJX3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78534285-e1d9-46de-8aba-3df39c78f7cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a5b9ab-78d2-494d-8555-ddef3fba32ae

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 190/1301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RHOF | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 66/556 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs757261415; called by muse, mutect2, varscan2
- B3GNT9 | c.934T>A p.F312I | Missense Mutation (SNP) | VAF 60/525 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRRAP | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 110/320 reads (34%) | called by mutect2, varscan2
- CRYBB1 | c.30G>A p.S10= | Silent (SNP) | VAF 109/586 reads (19%) | catalogued as rs141362656; called by muse, mutect2, varscan2
